Somatic mutation profile of tumor specimen MBCProject_0006_T3_WES (aliquot MBCProject_0006_T3_WES_1) from CMI case MBCProject_0006, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 37.5 years (13,683 days).
Specimen MBCProject_0006_T3_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9bad847-332d-4d7f-b518-0f0889ada27d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0006_SALIVA (Saliva), aliquot MBCProject_0006_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d89fda88-ca7a-483f-b2c5-da36d33e2205

The open-access MAF lists 62 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 6, 5'UTR 4, RNA 3, Nonsense Mutation 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC6 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 98/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202080674, CM980625, COSV63389526, COSV63392567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THOC6 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs763344375, CM164534, COSV50188158; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 86/218 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs201929281; called by muse, mutect2, varscan2
- ARHGAP4 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs374436435; called by muse, mutect2, varscan2
- CNOT1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57784161; called by muse, mutect2, varscan2
- DENND2C | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as rs189506550, COSV67921087; called by muse, mutect2, varscan2
- DMRTA1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753272129; called by muse, mutect2, varscan2
- GPR45 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.218); catalogued as rs970662249, COSV51523382; called by muse, mutect2
- MTF2 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs759180756, COSV64769675; called by muse, mutect2, varscan2
- MYO9A | c.4948A>G p.T1650A | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs747138214; called by muse, mutect2, varscan2
- PCDHAC1 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376173105, COSV53872551; called by muse, mutect2, varscan2
- PLCG2 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV63876529; called by muse, mutect2, varscan2
- RLIM | c.147T>G p.D49E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1287003301; called by muse, mutect2, varscan2
- STK36 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770755293, COSV55305910; called by muse, mutect2, varscan2
- TG | c.5918T>C p.L1973P | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs762988037; called by muse, mutect2, varscan2
- ZBTB48 | c.1171_1173del p.K391del | In Frame Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs749439559; called by pindel, varscan2
- ARHGAP4 | c.2023G>C p.A675P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CDH12 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 71/232 reads (31%) | called by muse, mutect2, varscan2
- INF2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KLK2 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LGR6 | c.2021T>G p.V674G (on ENST00000367278 / NM_001017403.1; = p.V622G on NM_021636.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- MMP8 | c.938T>A p.V313D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- MRPS11 | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NPAS2 | c.1965G>T p.Q655H | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PAK4 | c.1582C>G p.R528G | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARN | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLPP4 | c.617A>G p.D206G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, varscan2
- POLR2M | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2, varscan2
- RPH3A | c.1580C>A p.T527N (on ENST00000389385 / NM_001143854.2; = p.T523N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SGSM2 | c.2548C>G p.L850V (on ENST00000426855 / NM_001098509.2; = p.L895V on NM_014853.3) | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TOMM20L | c.397A>C p.I133L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPA1 | c.2201C>A p.T734N | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- WFDC8 | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ABHD13 | c.888G>T p.G296= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as rs1345326909; called by muse, mutect2, varscan2
- AC013489.1 | c.1368C>T p.S456= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as rs778791316, COSV51551039; called by muse, mutect2, varscan2
- BCAM | c.579G>A p.E193= | Silent (SNP) | VAF 48/137 reads (35%) | called by muse, mutect2, varscan2
- C12orf66 | c.447C>T p.L149= | Silent (SNP) | VAF 40/214 reads (19%) | called by mutect2, varscan2
- CDH2 | c.2049A>T p.T683= | Silent (SNP) | VAF 19/400 reads (5%) | called by muse, mutect2
- HEATR3 | c.1008C>G p.V336= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2
- KLK5 | c.318C>T p.A106= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100306835; called by muse, mutect2, varscan2
- MFSD3 | c.660C>T p.G220= | Silent (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- NLRX1 | c.423C>T p.L141= | Silent (SNP) | VAF 102/232 reads (44%) | catalogued as rs1397893507; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SLC66A3 | c.216C>G p.L72= | Silent (SNP) | VAF 60/193 reads (31%) | catalogued as COSV99706142; called by muse, mutect2, varscan2
- STK32B | c.570A>G p.E190= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs746317072; called by muse, mutect2, varscan2
- UBE2E3 | c.111A>G p.E37= | Silent (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- AC079612.1 | n.252C>T | RNA (SNP) | VAF 129/395 reads (33%) | catalogued as rs772152301; called by muse, mutect2, varscan2
- AC136604.1 | chr5:179652300 C>A | 3'Flank (SNP) | VAF 115/474 reads (24%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9339C>A | Intron (SNP) | VAF 131/506 reads (26%) | catalogued as COSV73145210; called by muse, mutect2, varscan2
- ADAM6 | n.1084G>C | RNA (SNP) | VAF 59/236 reads (25%) | called by muse, mutect2, varscan2
- BPNT2 | c.647-838T>A | Intron (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs73150876; called by muse, mutect2
- CNTRL | c.-420G>T | 5'UTR (SNP) | VAF 103/389 reads (26%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4039-109G>C | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- DMD | c.-29del | 5'UTR (DEL) | VAF 62/162 reads (38%) | catalogued as rs398123823; ClinVar: likely benign; called by mutect2, varscan2
- MTRR | c.1758-20dup | Intron (INS) | VAF 19/122 reads (16%) | called by pindel, varscan2
- RHBDD1 | c.655+98C>G | Intron (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- RIMKLB | chr12:8777620 A>C | 3'Flank (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- SLC12A6 | c.-39G>A | 5'UTR (SNP) | VAF 45/187 reads (24%) | catalogued as COSV100182343; called by muse, mutect2, varscan2
- SMC3 | c.-18G>C | 5'UTR (SNP) | VAF 90/272 reads (33%) | called by muse, mutect2, varscan2
- ZNF812P | n.635G>C | RNA (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
